Somatic mutation profile of tumor specimen TCGA-GS-A9TX-01A (aliquot TCGA-GS-A9TX-01A-11D-A382-10) from TCGA case TCGA-GS-A9TX, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 37.5 years (13,708 days).
Specimen TCGA-GS-A9TX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44b290f1-c38d-483d-b59b-dfc6ecb38291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TX-10A (Blood Derived Normal), aliquot TCGA-GS-A9TX-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a54ad94-dc77-4e9c-94f0-bee58ed571f0

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 23/92 reads (25%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- AL592490.1 | c.1607T>G p.L536R | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101308185; called by muse, mutect2, varscan2
- CD74 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV50533111; called by muse, mutect2, varscan2
- CDC5L | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101015022; called by muse, mutect2, varscan2
- CELSR3 | c.1691T>G p.V564G | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99373462; called by muse, mutect2, varscan2
- CHRNA2 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs749494357, COSV99532220; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTN1 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100751343; called by muse, mutect2, varscan2
- DNAH9 | c.3722T>C p.F1241S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99305741; called by muse, mutect2
- LCMT2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV99980051; called by muse, mutect2
- LPCAT2 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | catalogued as rs780823856, COSV50895398; called by muse, mutect2, varscan2
- LTB | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1383320828, COSV101068565; called by muse, mutect2, varscan2
- MYO9B | c.3628G>A p.A1210T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs371651213, COSV68281838; called by muse, mutect2, varscan2
- OR2L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs138166879; called by muse, mutect2, varscan2
- PALD1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs150010151; called by muse, mutect2, varscan2
- PDPK1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99239258; called by muse, mutect2
- PRSS16 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100041724, COSV57915763; called by muse, mutect2, varscan2
- PTPN13 | c.5806G>A p.G1936R (on ENST00000411767 / NM_080683.3; = p.G1917R on NM_006264.3) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777872734, COSV100364694; called by muse, mutect2, varscan2
- REV1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV99300908; called by muse, mutect2, varscan2
- SCNN1G | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV100264168; called by muse, mutect2, varscan2
- SETMAR | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); catalogued as COSV100740865; called by muse, varscan2
- SLC27A6 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99322658; called by muse, mutect2, varscan2
- SOCS1 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100130341; called by muse, mutect2, varscan2
- STAT6 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55670660; called by muse, mutect2, varscan2
- UBA6 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100451692; called by muse, mutect2, varscan2
- USP39 | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100083772; called by muse, mutect2, varscan2
- ZDHHC6 | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV101024394, COSV99054849; called by muse, mutect2, varscan2
- ATL3 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- KCNMB3 | c.628del p.I210Sfs*10 | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, varscan2
- PITRM1 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP1 | c.1086G>A p.K362= | Silent (SNP) | VAF 41/281 reads (15%) | catalogued as COSV56297695, COSV99775348; called by mutect2, varscan2
- DNMT3A | c.912C>T p.S304= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV53059495; called by muse, mutect2
- IGLC2 | c.198C>T p.Y66= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs776176899; called by muse, varscan2
- IGLC3 | c.210C>T p.S70= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as rs1342520202; called by muse, varscan2
- LRP1B | c.1081C>A p.R361= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs762774627, COSV101256443, COSV67254380; called by muse, mutect2, varscan2
- MAN2B1 | c.2886C>T p.R962= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs142797984; ClinVar: uncertain significance; called by mutect2, varscan2
- REEP1 | c.319C>T p.L107= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV51259934; called by muse, mutect2
- SLC7A14 | c.1137C>T p.S379= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99200496; called by muse, mutect2, varscan2
